Surgical pathology report (de-identified scan), TCGA case TCGA-78-7159, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7159-01A (Primary Tumor).

HISTORY

Left upper lobe mass. No preoperative tissue diagnosis.

MACROSCOPIC

One specimen submitted.

The specimen is labelled 'left upper lobe wedge resection' and consists of a wedge of lung tissue, 130 x 70 x 30 mm. The specimen bears a line of staples 110 mm in length. Protruding from one aspect of the pleural surface is a palpable mass. The pleura is free and mobile over the mass. 35 mm away from this lesion is a firm pleural plaque, 30 mm in diameter. Elsewhere the pleura shows some irregular grey and white discolouration. Serial slicing reveals a well defined yellowish white tumour mass, 25 mm in greatest diameter, approximately 2 mm deep to the pleura. The cut surface shows small areas of yellowish necrosis. The tumour is at least 25 mm clear of the stapled surgical margin. No other lesions are identified. The uninvolved lung shows severe emphysema. The mass lesion has been sampled for Microbiology and for [REDACTED]. [1A-1B tumour with overlying pleura; 1C-1D pleural plaque for decalcification; 1E-1F uninvolved lung parenchyma.]

MICROSCOPY

Sections reveal a peripherally located moderately differentiated adenocarcinoma demonstrating predominantly acinar and focal solid architecture. The tumour is positive for CK7 and TTF1 and negative for CK20. Zones of geographic necrosis are evident within the confines of the tumour. The tumour does not involve the pleura and is macroscopically clear of the intraparenchymal stapled margin. No lymphatic or vascular invasion is identified and no perineural permeation by tumour is seen. Immediately adjacent alveolated lung parenchyma shows organising pneumonia and acute bronchopneumonia. Remaining lung shows emphysema. Focal areas of pleural and subpleural fibroelastotic scarring with calcification are noted. No granulomas are seen.

SUMMARY

Left upper lobe wedge resection:

Moderately differentiated adenocarcinoma.

Tumour size 25mm.

Pleura not involved.

Clear of margin.

No lymphatic, vascular or perineural invasion.

Pathological stage: T1.

Immediately adjacent alveolated lung parenchyma shows organising pneumonia and acute bronchopneumonia; remaining lung shows emphysema with areas of pleural and subpleural fibroelastotic scarring.

[REDACTED]

T-28000 M-81403 P1-03000

[REDACTED]

Source: NCI Genomic Data Commons file 4e2c9725-79f3-44e0-bbd5-4c8fc1cd5e96 (TCGA-78-7159.ABB2F0E8-B167-4FFB-A52D-2116D4A919C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).